Somatic mutation profile of tumor specimen 0DL8QK from CCDI case PBBZER, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.5 years (196 days).
Specimen 0DL8QK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0860afe1-3685-4937-9987-34dbeb2fb5ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL8Q0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7356802d-83be-4c3f-92f2-51637a1711ec

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLGAP2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 31/739 reads (4%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.988); catalogued as rs1308791941, COSV70104172; called by muse, mutect2
- FLYWCH1 | c.1439C>T p.P480L (on ENST00000253928 / NM_001308068.2; = p.P479L on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 203/548 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs757850948, COSV54148732; called by muse, mutect2, varscan2
- OR2AJ1 | c.21T>C p.T7= | Silent (SNP) | VAF 32/488 reads (7%) | called by muse, mutect2
